FM case AD12881 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/78174c19-e0b2-477f-893b-f9084e0b35d5

Male, 56.3 years: Small cell carcinoma, NOS (ICD-O-3 8041/34) of the lung; metastasis biopsied or resected from the brain. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Metastatic.
